Somatic mutation profile of tumor specimen 0DPYE6 from CCDI case PBCEHY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Plasmacytoma, extramedullary; Tissue or organ of origin: Cauda equina; Age at diagnosis: 16.2 years (5,902 days).
Specimen 0DPYE6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dd0f3f1-2b71-41ec-bd32-be219ac332bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPYD9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89f20745-d0e2-4c00-bbdf-4a5dd0a258e2

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Del 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POLD3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 55/715 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as rs1319080479; called by muse, mutect2
- TNIP1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1238772178; called by muse, mutect2
- CCAR2 | c.806del p.L269Rfs*75 | Frame Shift Del (DEL) | VAF 188/879 reads (21%) | called by mutect2, pindel, varscan2
- NF2 | c.719_729del p.G240Vfs*2 | Frame Shift Del (DEL) | VAF 167/449 reads (37%) | called by mutect2, pindel, varscan2
- THBS1 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 66/599 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSWIM4 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); called by muse, mutect2
- UROC1 | c.1689C>T p.D563= | Silent (SNP) | VAF 25/429 reads (6%) | catalogued as rs576867756, COSV52029999; called by muse, mutect2
